Gene-level copy-number profile of tumor specimen C3N-03916-03 from CPTAC case C3N-03916, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 74.5 years (27,214 days).
Specimen C3N-03916-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Shoulder; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a5bee73-04da-4ab9-83f0-5a812de6f46c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03916-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,823 have no estimate.
https://portal.gdc.cancer.gov/files/32d87052-d4db-435d-9c78-cfef467938e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,418; copy number 1: 7,345; copy number 2: 34,191; copy number 3: 9,517; copy number 4: 3,302; copy number 5: 2,342; copy number 6: 317; copy number 7: 294; copy number 8: 53; copy number 9: 8; copy number 10: 1; copy number 11: 4; copy number 14: 3; copy number 16: 1; copy number 19: 1; copy number 33: 3.

Homozygous deletions (total copy number 0; autosomes only): 806 genes in 334 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:55,868,254–56,477,687, 5 genes (within-gene range 0–1): LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1.
- chr2:207,166,120–207,248,668, 6 genes (within-gene range 0–2): MYOSLID, MIR7845, AC007879.1, AC007879.3, AC007879.5, AC007879.2.
- chr3:6,892,632–8,611,924, 8 genes (within-gene range 0–2): GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1, LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P.
- chr3:17,871,729–18,955,049, 9 genes (within-gene range 0–2): AC104297.1, PDCL3P3, AC132807.1, AC132807.2, SATB1, AC144521.1, SATB1-AS1, RAD23BP1, RNU6-138P.
- chr3:29,926,811–31,455,894, 15 genes (within-gene range 0–2): RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1.
- chr3:35,638,945–36,170,448, 5 genes: ARPP21, ARPP21-AS1, MIR128-2, AC104308.1, RFC3P1.
- chr3:62,398,346–63,616,924, 11 genes (within-gene range 0–1): CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134.
- chr3:139,837,220–140,577,397, 6 genes (within-gene range 0–2): AC016933.1, TRMT112P5, CLSTN2, AC010181.1, AC010181.2, CLSTN2-AS1.
- chr4:69,181,660–69,250,815, 5 genes (within-gene range 0–1): AC111000.1, AC111000.4, UGT2B11, AC114797.1, AC114786.1.
- chr5:57,395,060–57,751,717, 5 genes (within-gene range 0–1): AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC106822.1.
- chr5:76,075,531–76,353,939, 10 genes (within-gene range 0–2): SAP18P1, AC026774.2, AC026774.1, SV2C, RNA5SP186, AC113404.2, AC113404.3, HMGN2P4, PDCD5P2, AC113404.1.
- chr5:158,424,585–159,099,916, 6 genes (within-gene range 0–1): AC091979.1, AC091979.2, AC091939.1, EBF1, AC136424.2, AC136424.1.
- chr6:81,724,722–82,169,391, 6 genes (within-gene range 0–1): AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1.
- chr6:91,521,660–91,816,428, 7 genes: MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1.
- chr8:118,761,856–119,108,455, 6 genes (within-gene range 0–1): RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2.
- chr8:120,535,745–121,119,754, 6 genes (within-gene range 0–2): SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1.
- chr8:125,648,327–126,292,788, 8 genes (within-gene range 0–2): AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1.
- chr8:130,780,301–131,432,869, 6 genes: ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72.
- chr9:101,449,801–101,793,756, 8 genes: AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4.
- chr9:116,425,225–118,072,314, 16 genes (within-gene range 0–1): ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1.
- chr10:104,641,290–105,820,349, 6 genes: SORCS3, SORCS3-AS1, RNU6-463P, PPIAP38, YWHAZP5, LINC02627.
- chr10:108,708,539–109,239,746, 5 genes: LINC02661, MAPKAPK5P1, RN7SKP278, RNU5B-6P, RNU6-839P.
- chr11:15,481,808–15,758,898, 5 genes: AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1.
- chr11:21,000,881–21,383,909, 5 genes (within-gene range 0–1): RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337.
- chr11:29,159,956–29,989,328, 8 genes (within-gene range 0–1): AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2.
- chr11:79,604,967–81,556,425, 10 genes: AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, MTND4LP18, MTND6P25.
- chr11:84,639,993–84,955,705, 5 genes (within-gene range 0–1): AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2.
- chr11:91,794,319–92,336,496, 5 genes: LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1.
- chr14:25,431,193–26,143,305, 5 genes: AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1.
- chr14:65,986,967–66,509,394, 7 genes (within-gene range 0–4): AL391261.2, YBX1P1, LINC02290, Y_RNA, AL359232.1, AL157997.1, CCDC196.
- chr14:78,231,281–79,791,263, 11 genes (within-gene range 0–1): RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1, AC026888.1, AC022469.1, AC022469.2, AC008056.2, AC008056.3, AC008056.1.
- chr15:47,184,101–48,050,507, 12 genes (within-gene range 0–2): SEMA6D, RN7SKP139, AC084882.1, AC023905.1, AC009558.1, AC009558.2, AC012050.1, AC044787.1, LINC01491, AC092078.2, AC092078.1, AC092078.3.
- chr15:86,173,198–87,047,303, 6 genes (within-gene range 0–1): AC016180.1, AGBL1-AS1, AC012229.1, AC016987.2, AC016987.1, AC078905.1.
- chr16:35,636,687–35,912,516, 28 genes: KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr16:52,005,487–52,280,638, 8 genes: C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22.
- chr16:55,259,969–55,333,588, 5 genes: AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2.
- chr16:64,364,781–65,646,947, 11 genes: AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1.
- chr17:33,529,787–33,689,174, 6 genes (within-gene range 0–1): AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2.
- chr20:39,757,202–40,126,357, 5 genes: AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1.
- chr22:27,019,369–27,061,247, 5 genes: AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,027 genes in 353 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:77,562,416–78,138,444, 21 genes, copy number 5: ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2, RNU6-1102P, AC103591.1, RNA5SP22.
- chr2:31,865,060–32,618,899, 19 genes, copy number 6–7: MEMO1, DPY30, AL121655.1, SPAST, AL121658.1, SLC30A6, DDX50P1, RNU6-647P, NLRC4, YIPF4, AL133245.1, BIRC6, BIRC6-AS1, AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4.
- chr2:134,964,485–135,898,978, 14 genes, copy number 5: MAP3K19, RAB3GAP1, SNORA40B, ZRANB3, G3BP1P1, R3HDM1, RNU6-512P, MIR128-1, UBXN4, LCT, Y_RNA, LCT-AS1, MCM6, MANEALP1.
- chr2:200,844,240–201,071,671, 13 genes, copy number 5 (within-gene range 3–5): BICD1P1, RNA5SP115, CLK1, Y_RNA, PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1, FAM126B, HNRNPA1P35, RPL23AP30.
- chr3:57,197,838–57,696,596, 18 genes, copy number 5: HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT.
- chr3:141,936,707–142,723,881, 17 genes, copy number 5: AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1.
- chr4:38,966,744–40,167,831, 38 genes, copy number 5–7: TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP, PDS5A, ELOCP33, RNA5SP159, AC098591.3, PABPC1P1, KRT18P25, AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3.
- chr4:47,831,330–48,861,817, 17 genes, copy number 5 (within-gene range 4–5): AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1.
- chr4:55,346,242–56,603,507, 34 genes, copy number 5–6: SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1.
- chr4:70,592,256–71,030,914, 13 genes, copy number 6–7: AMBN, ENAM, AC009570.2, JCHAIN, UTP3, RNU6-520P, RNU6-784P, AC009570.1, RUFY3, GRSF1, RNU6-891P, MOB1B, DCK.
- chr4:82,275,071–82,581,384, 13 genes, copy number 5–6: BIN2P1, AC124016.2, HNRNPD, AC124016.1, IGBP1P4, SNORD42, HNRNPDL, ENOPH1, TMEM150C, RPL7AP26, AC067942.1, AC067942.3, AC067942.2.
- chr4:139,015,781–139,476,609, 18 genes, copy number 6: NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1, RAB33B.
- chr4:158,666,675–159,375,322, 15 genes, copy number 5–6: C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1.
- chr4:164,877,178–165,208,549, 21 genes, copy number 5–6 (within-gene range 3–6): APELA, TRIM60P14, AC106872.3, AC106872.12, FAM218BP, AC106872.10, AC106872.5, NACA3P, AC106872.1, TRIM61, FAM218A, AC106872.4, AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P, TMEM192.
- chr4:185,051,081–185,535,507, 15 genes, copy number 5–6: LINC02436, AC093824.1, AC093824.2, SLC25A4, CFAP97, SNX25, LRP2BP, AC112722.1, ANKRD37, UFSP2, Y_RNA, C4orf47, CCDC110, AC106897.1, PDLIM3.
- chr4:187,970,273–189,002,075, 20 genes, copy number 5–6: AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1.
- chr6:105,919–6,007,605, 125 genes, copy number 5–9 (broad region; genes not listed).
- chr6:6,450,356–18,368,644, 186 genes, copy number 5–8 (broad region; genes not listed).
- chr6:19,612,755–21,602,383, 23 genes, copy number 5–8: KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:26,156,329–38,154,624, 668 genes, copy number 5–7 (broad region; genes not listed).
- chr6:41,228,339–45,664,349, 142 genes, copy number 5 (broad region; genes not listed).
- chr6:56,457,987–57,856,468, 17 genes, copy number 5–14: DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3.
- chr7:23,100,214–23,832,513, 25 genes, copy number 5 (within-gene range 3–5): KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3.
- chr7:65,023,204–65,357,176, 14 genes, copy number 5–6: RNU6-1229P, CCT6P3, AC073210.2, SNORA22C, SNORA15B-1, AC073210.1, GTF2IP14, INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1.
- chr7:130,070,534–131,496,632, 43 genes, copy number 5–6 (within-gene range 4–6): KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS.
- chr7:139,025,706–139,448,843, 15 genes, copy number 5–8: ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P.
- chr7:143,532,749–143,902,198, 16 genes, copy number 5: AC073264.1, PAICSP5, CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C, RNU6-267P, CTAGE6, AC099548.2, PAICSP6, AC099548.1, TCAF2P1, TCAF1.
- chr7:152,128,879–152,676,141, 14 genes, copy number 5–7: YBX1P4, KMT2C, AC104692.2, AC104692.1, SEPTIN7P6, Y_RNA, FABP5P3, CCT8L1P, LINC01003, AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2.
- chr8:66,562,175–67,345,087, 20 genes, copy number 5–6: MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1.
- chr9:61,789,143–63,385,117, 49 genes, copy number 5: RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4, BMS1P10, AQP7P1, AL845321.1.
- chr9:63,703,065–66,642,277, 62 genes, copy number 5 (broad region; genes not listed).
- chr10:67,750,284–68,212,017, 16 genes, copy number 5: AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, RPL12P8, SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5, MYPN, RN7SKP202.
- chr14:30,893,799–31,488,039, 18 genes, copy number 5–6: STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33.
- chr14:44,860,316–45,135,319, 14 genes, copy number 5: DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3.
- chr15:21,328,380–21,951,323, 36 genes, copy number 5–8: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr15:58,588,809–58,865,303, 14 genes, copy number 5 (within-gene range 2–5): ADAM10, HMGB1P51, AC091046.1, HSP90AB4P, RN7SKP95, AC091046.2, AC090515.6, AC090515.3, SNORD3P1, AC090515.2, MINDY2, AC090515.5, AC090515.4, ZNF444P1.
- chr16:46,469,341–47,143,945, 23 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2.
- chr17:29,929,200–30,186,475, 13 genes, copy number 5 (within-gene range 4–5): EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5.
- chr18:20,946,906–21,893,996, 26 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P.
- chr21:7,744,962–13,120,807, 73 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
